Somatic mutation profile of tumor specimen TARGET-40-NAAHBI-01A (aliquot TARGET-40-NAAHBI-01A-01D) from TARGET case TARGET-40-NAAHBI, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 12.1 years (4,410 days).
Specimen TARGET-40-NAAHBI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0204429e-b84b-42bb-a445-80e686346f51.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAHBI-10A (Blood Derived Normal), aliquot TARGET-40-NAAHBI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/840d9e80-9511-4311-bd9f-bb7a3ae5668e

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Splice Site 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.919+1G>C p.X307_splice | Splice Site (SNP) | VAF 32/39 reads (82%) | hotspot (GDC flag); catalogued as rs1131691039, CD920913, CS107068, CS120864, COSV52683145, COSV52775982, COSV52814989; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- CASC3 | c.1078A>G p.R360G | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- POM121L2 | c.1062A>C p.K354N | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); called by mutect2, varscan2
- LAMA3 | c.5529C>A p.V1843= (on ENST00000313654 / NM_198129.4; = p.V234= on NM_000227.6) | Silent (SNP) | VAF 17/54 reads (31%) | called by muse, mutect2, varscan2
